Somatic mutation profile of tumor specimen TCGA-04-1356-01A (aliquot TCGA-04-1356-01A-01W-0492-08) from TCGA case TCGA-04-1356, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 62.6 years (22,855 days).
Specimen TCGA-04-1356-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 454e6a68-f176-422f-8475-28712338790a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1356-11A (Solid Tissue Normal), aliquot TCGA-04-1356-11A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff6f7a3b-fa85-4a67-9c17-69218786b166

The open-access MAF lists 78 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 17, Nonsense Mutation 3, In Frame Del 2, Frame Shift Del 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 307/411 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AIF1 | c.197A>T p.D66V | Missense Mutation (SNP) | VAF 97/313 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV61962410, COSV61962451; called by muse, mutect2, varscan2
- AQP7 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV99951383; called by muse, mutect2, varscan2
- ARHGAP35 | c.2012T>A p.L671Q | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68331198; called by muse, varscan2
- ARMCX3 | c.797T>A p.L266H | Missense Mutation (SNP) | VAF 41/463 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57870427; called by muse, mutect2
- BMP10 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 200/529 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV54895247; called by muse, mutect2, varscan2
- C12orf66 | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100320483; called by muse, mutect2, varscan2
- CACNA1S | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 78/639 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62939440; called by muse, mutect2, varscan2
- CARD18 | c.62C>A p.T21K | Missense Mutation (SNP) | VAF 166/270 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375563255, COSV73233178; called by muse, mutect2, varscan2
- CD163L1 | c.2972A>G p.H991R | Missense Mutation (SNP) | VAF 73/537 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.647); catalogued as COSV58016027; called by muse, mutect2, varscan2
- CNBD1 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 102/176 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV72976104; called by muse, mutect2, varscan2
- CNOT1 | c.4529C>G p.T1510S | Missense Mutation (SNP) | VAF 132/351 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as COSV55316602; called by muse, mutect2, varscan2
- COPG1 | c.1679G>C p.R560T | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV100135229; called by muse, mutect2, varscan2
- CSF2RB | c.1480C>A p.L494I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.129); catalogued as COSV53260425; called by muse, mutect2, varscan2
- DNAH17 | c.3529A>C p.N1177H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV67754290; called by muse, mutect2, varscan2
- ECE1 | c.1213T>G p.F405V | Missense Mutation (SNP) | VAF 85/126 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as COSV51664630; called by muse, mutect2, varscan2
- EHMT2 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as COSV100976932; called by muse, mutect2
- EML5 | c.2545G>T p.G849* | Nonsense Mutation (SNP) | VAF 16/415 reads (4%) | catalogued as COSV100714949; called by muse, mutect2
- EPHA1 | c.1699G>A p.V567I | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs555414886, COSV51970638; called by muse, mutect2, varscan2
- ETS1 | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV101200239; called by muse, mutect2, varscan2
- FADD | c.342G>C p.R114S | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs772999577, COSV57229245; called by muse, mutect2, varscan2
- FCN1 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV65662330; called by muse, mutect2
- HCN4 | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56083575; called by muse, mutect2, varscan2
- HUWE1 | c.6551G>A p.S2184N | Missense Mutation (SNP) | VAF 211/875 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs781884032, COSV53345378; called by muse, mutect2, varscan2
- INSRR | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV63873120; called by muse, mutect2, varscan2
- LARP7 | c.1237T>G p.S413A | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV60520934; called by muse, mutect2, varscan2
- LRFN2 | c.701C>A p.P234H | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); catalogued as COSV57827336; called by mutect2, varscan2
- MICAL3 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 244/662 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99259191; called by muse, mutect2, varscan2
- NUP160 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV65854363; called by muse, mutect2, varscan2
- PAPOLG | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV53182754; called by muse, mutect2, varscan2
- PFKFB3 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 57/146 reads (39%) | catalogued as COSV57988708; called by muse, mutect2, varscan2
- PLPPR4 | c.1330T>A p.S444T | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV64565767; called by muse, varscan2
- PODN | c.589A>C p.N197H (on ENST00000395871; = p.N149H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV57013573; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2171A>C p.Q724P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53452831; called by muse, mutect2, varscan2
- PPP1R10 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 154/709 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV100919744; called by muse, mutect2, varscan2
- PRAMEF20 | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 285/374 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV100326288; called by muse, varscan2
- PRPH2 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs935103151, COSV57837224; called by muse, mutect2, varscan2
- PRSS36 | c.1070G>A p.W357* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV51637280; called by muse, mutect2, varscan2
- PTPRU | c.2784C>A p.H928Q | Missense Mutation (SNP) | VAF 104/164 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV60527728; called by muse, mutect2, varscan2
- QSER1 | c.4828G>C p.E1610Q (on ENST00000399302; = p.E1739Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV101234614; called by muse, mutect2
- RAB14 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 40/643 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.158); catalogued as COSV99440696; called by muse, mutect2
- RBP5 | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 115/742 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56936230, COSV56936312; called by muse, mutect2, varscan2
- RFX3 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs757346391, COSV56515132; called by muse, mutect2, varscan2
- RNF31 | c.1192C>A p.L398I | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV53759504; called by muse, mutect2, varscan2
- RSF1 | c.4100A>G p.D1367G | Missense Mutation (SNP) | VAF 173/563 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV57839876; called by muse, mutect2, varscan2
- SCML1 | c.437G>A p.R146H (on ENST00000380041 / NM_001037540.3; = p.R119H on NM_006746.6) | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as rs768300603, COSV66240544; called by muse, mutect2, varscan2
- SEL1L2 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 59/82 reads (72%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.877); catalogued as rs139504161, COSV53152213; called by muse, mutect2, varscan2
- SERPINB1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV66313732; called by muse, mutect2, varscan2
- SHE | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV59071781; called by muse, mutect2, varscan2
- SLC6A13 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 64/1906 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753692670, COSV100569662; called by muse, mutect2
- SPTA1 | c.490G>C p.V164L | Missense Mutation (SNP) | VAF 128/531 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63752987; called by muse, mutect2, varscan2
- TP53TG5 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as rs186331008; called by muse, mutect2, varscan2
- WWTR1 | c.964A>T p.S322C | Missense Mutation (SNP) | VAF 139/1030 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1230014926, COSV100640769; called by muse, mutect2, varscan2
- ZNF224 | c.486C>G p.H162Q | Missense Mutation (SNP) | VAF 188/282 reads (67%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV100425335, COSV61242297; called by muse, mutect2, varscan2
- ZSWIM2 | c.1637A>G p.K546R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54575435; called by muse, mutect2, varscan2
- ABCF1 | c.695_709del p.G232_E236del | In Frame Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- MED28 | c.80_92del p.A27Gfs*30 | Frame Shift Del (DEL) | VAF 42/172 reads (24%) | called by mutect2, pindel, varscan2
- SLC49A4 | c.799_810del p.L267_R270del | In Frame Del (DEL) | VAF 37/166 reads (22%) | called by mutect2, pindel, varscan2
- TJP1 | c.3534_3550del p.H1178Qfs*10 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | called by mutect2, pindel, varscan2
- ABCG5 | c.1182G>T p.L394= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV53210778; called by muse, mutect2, varscan2
- ACCSL | c.1005C>A p.I335= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV66581207; called by muse, varscan2
- APLP1 | c.1809C>G p.L603= (on ENST00000221891 / NM_001024807.3; = p.L602= on NM_005166.4) | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV55702026, COSV55703364; called by muse, mutect2, varscan2
- DCUN1D3 | c.348T>C p.N116= | Silent (SNP) | VAF 115/283 reads (41%) | catalogued as COSV60953339; called by muse, mutect2, varscan2
- DRP2 | c.468C>T p.G156= | Silent (SNP) | VAF 81/282 reads (29%) | catalogued as rs918973376, COSV65810321; called by muse, mutect2, varscan2
- HMCN1 | c.576A>C p.T192= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs377577511; called by muse, mutect2, varscan2
- KRTAP5-3 | c.51T>C p.C17= | Silent (SNP) | VAF 118/153 reads (77%) | catalogued as COSV68790676; called by muse, mutect2, varscan2
- L1CAM | c.2553G>A p.T851= | Silent (SNP) | VAF 62/211 reads (29%) | catalogued as rs373921972, COSV62828051; called by muse, mutect2, varscan2
- LRRTM1 | c.753G>T p.S251= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV54441111, COSV99703378; called by muse, mutect2, varscan2
- NFATC1 | c.1701C>T p.H567= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as rs141454060; called by muse, mutect2, varscan2
- PKHD1L1 | c.12288G>A p.Q4096= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as COSV65742868; called by muse, mutect2, varscan2
- PPL | c.2301G>A p.L767= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV62046988; called by muse, mutect2, varscan2
- SHC4 | c.939T>C p.N313= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV60112266; called by muse, varscan2
- TNIP1 | c.306C>G p.A102= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV59306679; called by muse, mutect2, varscan2
- TULP3 | c.786A>G p.G262= | Silent (SNP) | VAF 23/349 reads (7%) | catalogued as rs755495863, COSV101237453; called by muse, mutect2
- VWF | c.4032C>T p.A1344= | Silent (SNP) | VAF 20/261 reads (8%) | catalogued as COSV54620276; called by muse, mutect2
- ZNF474 | c.528G>A p.L176= | Silent (SNP) | VAF 72/112 reads (64%) | catalogued as COSV99681959; called by mutect2, varscan2
- ARMC5 | c.1864+53C>A | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV51656417; called by muse, mutect2
- CDH23 | c.3369+488G>A | Intron (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99818181; called by muse, mutect2
